TCGA case TCGA-DB-A4XA — Brain Lower Grade Glioma (TCGA-LGG)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Mayo Clinic - Rochester. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ae61a71e-53a1-4884-a4a6-729744d1c309

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 30 years; Vital status: Alive.

Diagnoses (1)
1. Mixed glioma: ICD-O-3 morphology code: 9382/3; ICD-10 code: C71.2; Tissue or organ of origin: Temporal lobe; Site of resection or biopsy: Nervous system, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 30.7 years (11,195 days); Year of diagnosis: 2012; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 573 days (1.6 years); First symptom longest duration: >=181 Days; First symptom prior to diagnosis: Seizures; Sites of involvement: Brain, Parietal; Supratentorial localization: Cerebral Cortex.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 89 days; Days to treatment end: 128 days; Treatment dose: 5,400 cGy; Treatment outcome: Stable Disease; Number of fractions: 30; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Antiseizure Treatment; Timepoint category: Preoperative.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; Radiation Therapy, NOS to Head, Face or Neck, NOS, prior to diagnosis; Steroid Therapy, preoperative.

Follow-up (2 entries)
- Days to follow up: 313 days; Disease response: With Tumor.
- Follow-up contact recording only the day: day 573.

Molecular and laboratory tests
- IDH1 mutation, nos (IHC): Positive.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Risk factors: Seizure.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DB-A4XA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 140 mg.
  Slide TCGA-DB-A4XA-01A-01-TSA: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 15; Percent necrosis: 0; Percent stromal cells: 5; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-DB-A4XA-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-DB-A4XA-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Central nervous system; Histologic diagnosis: Oligoastrocytoma; History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; History ionizing radiation to head: No; Tumor status: With tumor; Tumor site: Supratentorial, Parietal Lobe; History seizures: Yes; History headaches: No; Symp changes mental status: No; Symp changes visual: No; Symp changes sensory: No; Symp changes motor movement: No; First symptom longest duration: > 181 Days; History asthma: No; History eczema: No; Histor hay fever: No; History dust mold allergy: No; Allergy food diagnosis indicator: No; Allergy animals insects diagnosis indicator: No; History neoadjuvant steroid treatment: No; History neoadjuvant medication: Yes; Family history brain tumor: No; Idh1 mutation test indicator: Yes; Idh1 mutation found: Yes; Inherited genetic syndrome indicator: No; New tumor event diagnosis indicator: No.
- Follow-up form: Lost to follow-up: Yes.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 573 days; disease-specific survival: no event (censored), 573 days; progression-free interval: no event (censored), 573 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-DB-A4XA-01A-11D-A26L-01): tumor purity 0.77, ploidy 1.94, whole-genome doublings 0.
